Somatic mutation profile of tumor specimen d6d42051-ad8e-4fb2-8cfc-829353 (aliquot d6d42051-ad8e-4fb2-8cfc-829353_D6) from CPTAC case 01BR025, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 62.0 years (22,629 days).
Specimen d6d42051-ad8e-4fb2-8cfc-829353: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 363388b9-4701-4132-8960-2e51649262fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 110009db-7606-406d-a9f8-1aa86c (Blood Derived Normal), aliquot 110009db-7606-406d-a9f8-1aa86c_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f69b8292-c41c-4437-9469-3c951775786a

The open-access MAF lists 1 somatic variant for this specimen: 1 silent.
By variant classification: Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RNPEP | c.393C>A p.R131= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
